Somatic mutation profile of tumor specimen TCGA-B5-A0K0-01A (aliquot TCGA-B5-A0K0-01A-11W-A062-09) from TCGA case TCGA-B5-A0K0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 48.8 years (17,810 days).
Specimen TCGA-B5-A0K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc7b8f2c-506a-4874-a725-6cd8cd324ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K0-10A (Blood Derived Normal), aliquot TCGA-B5-A0K0-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50973d29-975c-4ee2-8b19-b54d1b1727a8

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 3, Splice Site 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 44/133 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 47/144 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6144G>A p.W2048* | Nonsense Mutation (SNP) | VAF 105/253 reads (42%) | catalogued as COSV61377394; called by muse, mutect2, varscan2
- CARM1 | c.1825T>C p.*609Qext*58 | Nonstop Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53403555; called by muse, mutect2, varscan2
- DTD2 | c.326A>T p.N109I | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60427925; called by muse, mutect2, varscan2
- FAT4 | c.8782G>T p.E2928* | Nonsense Mutation (SNP) | VAF 41/147 reads (28%) | catalogued as COSV58684336; called by muse, mutect2, varscan2
- IVL | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV64216208; called by muse, mutect2
- MYT1L | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.964); catalogued as COSV67719851; called by muse, mutect2, varscan2
- NAALADL2 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as COSV70794786; called by muse, mutect2, varscan2
- NUTM1 | c.1415T>C p.M472T | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs529647220, COSV59216748; called by muse, mutect2, varscan2
- PEAK1 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266732669, COSV56935182; called by muse, mutect2, varscan2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- PRUNE2 | c.2461A>G p.T821A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs753281680, COSV65041413; called by muse, mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2, varscan2
- TBC1D10A | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747299456, COSV53164195; called by muse, mutect2, varscan2
- TMEM145 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as COSV56625281; called by muse, mutect2, varscan2
- TTC31 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52035145; called by muse, mutect2, varscan2
- ZFAND3 | c.529+2T>G p.X177_splice | Splice Site (SNP) | VAF 70/162 reads (43%) | catalogued as COSV54725738; called by muse, mutect2, varscan2
- RAB2A | c.398_400del p.E133del | In Frame Del (DEL) | VAF 96/300 reads (32%) | called by pindel, varscan2
- FGD5 | c.1353C>T p.D451= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs374381042; called by muse, varscan2
- KDM5B | c.3036C>T p.D1012= | Silent (SNP) | VAF 81/154 reads (53%) | catalogued as rs769873701, COSV52507583; called by muse, mutect2, varscan2
- NAGPA | c.1368G>A p.A456= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs185563042, COSV56569309; called by muse, mutect2, varscan2
- PCDHB4 | c.2175G>T p.S725= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV52022302; called by muse, mutect2, varscan2
